Somatic mutation profile of tumor specimen 0DQB2Z from CCDI case PBCETX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.0 years (5,115 days).
Specimen 0DQB2Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0e34d305-178b-4ab7-9053-f76a2eeaf8df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQB24 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a99ae9d3-d624-45ff-a278-65d48443ab16

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 3, 3'UTR 2, Nonsense Mutation 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>G p.S33C | Missense Mutation (SNP) | VAF 211/587 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic /  other; called by muse, mutect2, varscan2
- NIPBL | c.2260C>T p.R754* | Nonsense Mutation (SNP) | VAF 262/805 reads (33%) | catalogued as rs587783899, COSV56957824; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARHGAP21 | c.3763C>A p.R1255S | Missense Mutation (SNP) | VAF 188/617 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57605752; called by muse, mutect2, varscan2
- BMPER | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 174/507 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs376351419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCC1 | c.623G>A p.R208H (on ENST00000356970 / NM_001377464.1; = p.R158H on NM_015127.5) | Missense Mutation (SNP) | VAF 260/688 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.011); catalogued as rs141116625; ClinVar: uncertain significance; called by muse, varscan2
- FMR1 | c.967G>T p.E323* | Nonsense Mutation (SNP) | VAF 238/393 reads (61%) | catalogued as COSV99503349; called by muse, mutect2, varscan2
- INSIG1 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 183/522 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376290152; called by muse, mutect2, varscan2
- KPRP | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 175/492 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs766232082, COSV64221817, COSV64222140; called by muse, mutect2, varscan2
- MEN1 | c.470T>C p.L157S | Missense Mutation (SNP) | VAF 14/317 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM129472; called by muse, mutect2
- RPS6KA1 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766775987, COSV64810487; called by muse, mutect2, varscan2
- TRIM3 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 109/316 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs747082474, COSV61985983; called by muse, mutect2, varscan2
- UNC45B | c.1586G>T p.R529L | Missense Mutation (SNP) | VAF 183/485 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV99269216; called by muse, mutect2, varscan2
- ATG2B | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 30/572 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.112); called by muse, mutect2
- GALNT16 | c.1132T>C p.Y378H | Missense Mutation (SNP) | VAF 159/377 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- LPCAT3 | c.1322T>C p.L441P | Missense Mutation (SNP) | VAF 30/856 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- PIWIL3 | c.2633G>A p.R878H | Missense Mutation (SNP) | VAF 55/582 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.072); called by muse, mutect2
- PRAMEF15 | c.646T>C p.C216R | Missense Mutation (SNP) | VAF 30/319 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- RALGAPA2 | c.4402G>A p.G1468R | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMARCA4 | c.2648G>T p.G883V | Missense Mutation (SNP) | VAF 233/390 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ZNF510 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 51/1028 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- ANO8 | c.1477C>A p.R493= | Silent (SNP) | VAF 69/295 reads (23%) | catalogued as rs762329366; called by muse, mutect2, varscan2
- EIF4A1 | c.159G>A p.E53= | Silent (SNP) | VAF 196/570 reads (34%) | called by muse, mutect2, varscan2
- ULBP1 | c.654C>G p.T218= | Silent (SNP) | VAF 122/237 reads (51%) | catalogued as COSV99997966; called by muse, mutect2, varscan2
- AC097637.3 | n.666C>G | RNA (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- BHLHE40 | c.151-35C>G | Intron (SNP) | VAF 129/330 reads (39%) | called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 23/542 reads (4%) | called by muse, mutect2
- PLA1A | c.*15G>C | 3'UTR (SNP) | VAF 144/437 reads (33%) | called by muse, mutect2, varscan2
